Somatic mutation profile of tumor specimen ASCProject_0167_T3_WES (aliquot ASCProject_0167_T3_WES_1) from CMI case ASCProject_0167, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 65.6 years (23,947 days).
Specimen ASCProject_0167_T3_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Chest Wall; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fcb95fd-73f3-4865-a629-c7bdba02f4f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0167_SALIVA (Saliva), aliquot ASCProject_0167_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e212d02-b9a8-431d-b800-1f7f4ae0ca6e

The open-access MAF lists 33 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Intron 5, Nonsense Mutation 4, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM30 | c.1858A>T p.K620* | Nonsense Mutation (SNP) | VAF 12/92 reads (13%) | catalogued as rs1454902574, COSV65560218, COSV65560365; called by muse, mutect2, varscan2
- CAPN8 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs763781240; called by muse, mutect2, varscan2
- CCDC85A | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775195592, COSV101339464, COSV68154085; called by muse, mutect2, varscan2
- ESR1 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866869178, COSV52780667; called by muse, mutect2, varscan2
- METTL3 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52968799; called by muse, mutect2, varscan2
- NFAT5 | c.460A>G p.N154D | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375170983; called by muse, mutect2, varscan2
- PGR | c.2418G>C p.Q806H | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99678660; called by muse, mutect2, varscan2
- STK26 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs776577670; called by muse, mutect2, varscan2
- TTC21A | c.3043G>T p.E1015* | Nonsense Mutation (SNP) | VAF 13/113 reads (12%) | catalogued as COSV57182976; called by muse, mutect2, varscan2
- ADAMTSL3 | c.74C>A p.T25K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DNAJC13 | c.5872G>T p.E1958* | Nonsense Mutation (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- ERICH3 | c.134G>T p.R45I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM124B | c.1226G>A p.S409N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- FGF7 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GJA1 | c.136G>T p.G46* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRK2 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- NLRP9 | c.903_909del p.E302Sfs*15 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | called by mutect2, pindel, varscan2
- PRAG1 | c.2413T>G p.S805A | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SCRIB | c.4238A>G p.E1413G | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ACACB | c.6996C>A p.R2332= | Silent (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.75A>C p.T25= | Silent (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- COG1 | c.1137C>T p.L379= | Silent (SNP) | VAF 27/196 reads (14%) | catalogued as rs755774467, COSV55429610; called by muse, mutect2, varscan2
- HMCN1 | c.13341G>A p.V4447= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as rs1312413984; called by muse, mutect2
- NLRP13 | c.2532C>T p.C844= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as rs569519554; called by muse, mutect2
- THEMIS | c.1923A>G p.K641= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2
- ZNF326 | c.366C>T p.F122= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as rs142094932; called by muse, mutect2, varscan2
- CBFA2T2 | c.62-6506C>A | Intron (SNP) | VAF 8/77 reads (10%) | called by muse, varscan2
- DBF4B | c.1189+942G>A | Intron (SNP) | VAF 16/109 reads (15%) | catalogued as rs1360667881; called by muse, mutect2, varscan2
- ITSN2 | c.3991-41G>C | Intron (SNP) | VAF 20/143 reads (14%) | called by muse, mutect2, varscan2
- OFCC1 | n.1581C>A | RNA (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- PCDH11X | c.3144+24821_3144+24829del | Intron (DEL) | VAF 8/90 reads (9%) | called by mutect2, pindel
- REV3L | c.9043-618T>A | Intron (SNP) | VAF 5/37 reads (14%) | catalogued as rs1356395055; called by muse, mutect2
